Somatic mutation profile of tumor specimen ALCH-B485-TTP1-A (aliquot ALCH-B485-TTP1-A-12-0-D-A799-36) from ALCHEMIST case ALCH-B485, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.2 years (24,558 days).
Specimen ALCH-B485-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e0b16b2-ef11-4b25-ae6e-7adfff1f7b1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B485-NB1-A (Blood Derived Normal), aliquot ALCH-B485-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfa61d29-3989-4a88-a735-67cb1621ca73

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, RNA 3, Nonsense Mutation 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKIB1 | c.1972C>G p.R658G | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56065767; called by muse, mutect2
- ARHGAP9 | c.1828C>G p.Q610E (on ENST00000393797 / NM_001319850.2; = p.Q591E on NM_032496.4) | Missense Mutation (SNP) | VAF 21/229 reads (9%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.981); catalogued as COSV57368470; called by muse, mutect2
- GABRG2 | c.1343G>T p.C448F (on ENST00000361925 / NM_001375343.1; = p.C408F on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/538 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62723640; called by muse, mutect2, varscan2
- IGF2 | c.595G>A p.A199T (on ENST00000434045 / NM_001127598.3; = p.A143T on NM_000612.6) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs200836416, COSV56098202; called by muse, mutect2, varscan2
- OR51D1 | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 56/572 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62913916; called by muse, mutect2
- SCGB1D2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs141510840; called by muse, mutect2, varscan2
- SHISAL1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 9/185 reads (5%) | catalogued as COSV66987723; called by muse, mutect2
- SIRPD | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 22/395 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs761235171; called by muse, mutect2
- ZNF485 | c.1127A>T p.H376L | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1484752707; called by muse, mutect2
- ADGRE3 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CALCOCO2 | c.740T>G p.L247R | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC152 | c.328-4_333del p.X110_splice | Splice Site (DEL) | VAF 8/53 reads (15%) | called by mutect2, pindel
- ECD | c.442A>T p.I148F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- EPDR1 | c.484A>G p.T162A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FAT4 | c.4056C>G p.Y1352* | Nonsense Mutation (SNP) | VAF 7/160 reads (4%) | called by muse, mutect2
- HUWE1 | c.12076G>T p.V4026L | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); called by muse, mutect2
- IL21R | c.945G>C p.E315D | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MGAT3 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); called by muse, mutect2
- PBRM1 | c.1712T>G p.I571S | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SYN1 | c.1967C>A p.P656Q | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF727 | c.1025G>C p.C342S | Missense Mutation (SNP) | VAF 21/238 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CLTC | c.2187T>C p.F729= | Silent (SNP) | VAF 29/316 reads (9%) | catalogued as rs754867447; called by muse, mutect2
- PFDN5 | c.162C>T p.N54= | Silent (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- SEH1L | c.276A>G p.E92= | Silent (SNP) | VAF 16/197 reads (8%) | catalogued as rs764058717; called by muse, mutect2
- SEPTIN9 | c.519C>T p.P173= (on ENST00000427177 / NM_001113491.2; = p.P155= on NM_006640.4) | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as rs763954299, COSV61204147; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WSCD2 | c.315C>T p.G105= | Silent (SNP) | VAF 23/220 reads (10%) | catalogued as rs902928991; called by muse, mutect2
- ZNF577 | c.1050A>G p.G350= | Silent (SNP) | VAF 12/237 reads (5%) | called by muse, mutect2
- IFT74 | c.305+1711C>G | Intron (SNP) | VAF 32/371 reads (9%) | called by muse, mutect2
- MIR30B | n.16A>T | RNA (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- SNORD116-5 | n.75T>C | RNA (SNP) | VAF 30/466 reads (6%) | called by muse, mutect2
- SSPOP | n.14134G>T | RNA (SNP) | VAF 10/102 reads (10%) | catalogued as COSV65136520; called by muse, mutect2
